Somatic mutation profile of tumor specimen MMRF_2640_1_BM_CD138pos (aliquot MMRF_2640_1_BM_CD138pos_T1_KHS5U_L13406) from MMRF case MMRF_2640, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2640_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5450b1a7-53b3-497b-8471-018e77ffadd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2640_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2640_1_PB_WBC_C2_KHS5U_L13407; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c27e3398-5471-405c-a2c7-85bf6b207ed3

The open-access MAF lists 133 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 40, Silent 12, Intron 10, 5'UTR 8, Nonsense Mutation 4, 5'Flank 3, RNA 3, In Frame Del 2, 3'Flank 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL2 | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV54095123; called by muse, mutect2, varscan2
- ARVCF | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 139/435 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs778549957, COSV52889561; called by muse, mutect2, varscan2
- ATM | c.8161G>A p.D2721N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM149284, COSV53726516, COSV53771356; called by muse, mutect2, varscan2
- ATOH8 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200636678; called by muse, mutect2, varscan2
- BRSK2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs765073528; called by muse, mutect2, varscan2
- C10orf71 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60505052; called by muse, mutect2
- C15orf40 | c.48T>A p.N16K | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs1406816688; called by muse, mutect2
- C9 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200646202; called by muse, mutect2, varscan2
- CYLC2 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs746464948, COSV66336744; called by muse, mutect2, varscan2
- ENO4 | c.623dup p.Q210Afs*21 (on ENST00000622726; = p.Q209Afs*21 on NM_001242699.2) | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs761717176; called by mutect2, varscan2
- FAM209B | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 44/147 reads (30%) | catalogued as rs200395408; called by muse, mutect2, varscan2
- IGLV3-1 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 150/160 reads (94%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1426539348; called by muse, varscan2
- KLHDC7A | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs765237577; called by muse, mutect2, varscan2
- LAMB4 | c.675C>A p.N225K | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223475; called by muse, mutect2, varscan2
- LIPN | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs749704797; called by muse, mutect2, varscan2
- OTUD4 | c.1271G>A p.R424H (on ENST00000447906 / NM_001366057.1; = p.R359H on NM_001102653.1) | Missense Mutation (SNP) | VAF 81/83 reads (98%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1452207749, COSV104437422; called by muse, mutect2, varscan2
- PLA2G6 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs370151752; called by muse, mutect2, varscan2
- RP1L1 | c.2687G>T p.G896V | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs774135283; called by muse, mutect2, varscan2
- RPL9 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV54695690; called by muse, mutect2
- SPATA31D1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 218/718 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs202197407; called by muse, mutect2, varscan2
- TBC1D22A | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs563554988; called by muse, mutect2, varscan2
- TENM1 | c.5496G>T p.W1832C | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM138111; called by muse, mutect2, varscan2
- TENT5C | c.477_479del p.N159del | In Frame Del (DEL) | VAF 16/155 reads (10%) | catalogued as rs1403919133; called by pindel, varscan2
- TIE1 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as rs749447904; called by muse, mutect2, varscan2
- TNIK | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.115); catalogued as rs368871345; called by muse, mutect2, varscan2
- WNT10A | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs754010310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C9orf43 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CCDC146 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHL1 | c.1623C>G p.D541E (on ENST00000397491 / NM_001253387.1; = p.D557E on NM_006614.4) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYBB | c.147_161del p.L50_R54del | In Frame Del (DEL) | VAF 24/24 reads (100%) | called by mutect2, pindel
- DDX60L | c.636A>T p.K212N | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DENND1C | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 181/271 reads (67%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DGKE | c.509dup p.N170Kfs*2 | Frame Shift Ins (INS) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- DRD5 | c.914T>C p.F305S | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYS | c.7886G>T p.G2629V | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FMN1 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 155/232 reads (67%) | called by muse, mutect2, varscan2
- GNAT3 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFNL1 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2
- IGFBP3 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 80/114 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, varscan2
- IGLV3-21 | c.157T>C p.W53R | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LMNTD2 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.8108C>T p.S2703F | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MCL1 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, varscan2
- MORC1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- NT5C3B | c.666A>C p.K222N | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.346); called by muse, mutect2
- PPFIBP2 | c.2290C>T p.L764F | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIN1 | c.1571T>C p.M524T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPOR2 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 93/388 reads (24%) | called by muse, mutect2, varscan2
- SARS2 | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SMTNL1 | c.1013C>A p.A338E (on ENST00000399154; = p.A375E on NM_001105565.2) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TMSB4X | c.-14T>C | Splice Region (SNP) | VAF 15/17 reads (88%) | called by muse, mutect2, varscan2
- TPH2 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UBR4 | c.11128C>T p.R3710C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WASF3 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 188/191 reads (98%) | SIFT tolerated (0.7); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZBED4 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 101/314 reads (32%) | called by muse, mutect2, varscan2
- BCL11B | c.1536G>A p.A512= (on ENST00000357195 / NM_001282237.2; = p.A441= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as rs1033640599; called by muse, mutect2, varscan2
- CDH12 | c.1383G>A p.A461= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs377629401; called by muse, mutect2, varscan2
- DYNC2H1 | c.3897A>T p.V1299= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- FCSK | c.2463C>T p.T821= | Silent (SNP) | VAF 132/139 reads (95%) | called by muse, varscan2
- KRTAP16-1 | c.450A>G p.Q150= | Silent (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- OR1L6 | c.738C>T p.T246= (on ENST00000373684; = p.T210= on NM_001004453.2) | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2
- PHKB | c.27A>G p.A9= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs374068481; called by muse, mutect2, varscan2
- SALL3 | c.333G>A p.A111= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- SEMA5A | c.1251C>T p.V417= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- TMC6 | c.402G>A p.E134= | Silent (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- WFS1 | c.426G>A p.V142= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- ZDHHC24 | c.330C>T p.C110= | Silent (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- ABR | c.*2470C>G | 3'UTR (SNP) | VAF 59/89 reads (66%) | called by muse, mutect2, varscan2
- ACTBL2 | c.*1526G>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1374G>A | Intron (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- AGAP1 | c.*1829G>A | 3'UTR (SNP) | VAF 55/97 reads (57%) | catalogued as rs915039443; called by muse, mutect2, varscan2
- AGPAT4 | c.*4682C>A | 3'UTR (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.*635T>A | 3'UTR (SNP) | VAF 46/66 reads (70%) | catalogued as rs551558336, COSV62844179; called by mutect2, varscan2
- ATE1 | c.*17G>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- BCHE | c.*331G>T | 3'UTR (SNP) | VAF 48/174 reads (28%) | called by muse, varscan2
- BHMT2 | c.*236C>T | 3'UTR (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- C21orf62 | c.*1089C>T | 3'UTR (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- CD177P1 | n.28G>A | RNA (SNP) | VAF 113/177 reads (64%) | called by muse, mutect2, varscan2
- CLDN5 | chr22:19525134 A>G | 5'Flank (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936284 C>T | 3'Flank (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- CYP2U1 | c.*881T>G | 3'UTR (SNP) | VAF 56/57 reads (98%) | called by muse, mutect2, varscan2
- DUSP4 | c.*862G>T | 3'UTR (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- DYNAP | c.*180T>C | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- EGF | c.941-140C>T | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ENKUR | c.765-163_765-162del | Intron (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- FAM186A | chr12:50327110 G>A | 3'Flank (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- FAT3 | c.*468G>T | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- FEZ1 | c.*500G>T | 3'UTR (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- GABRG1 | c.*3533T>C | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- GIT2 | c.*513C>T | 3'UTR (SNP) | VAF 19/92 reads (21%) | catalogued as rs952330648; called by muse, mutect2, varscan2
- GRAP2 | c.*270G>A | 3'UTR (SNP) | VAF 129/189 reads (68%) | catalogued as rs1442999493; called by muse, mutect2, varscan2
- GRM8 | c.-86C>T | 5'UTR (SNP) | VAF 34/54 reads (63%) | called by muse, mutect2, varscan2
- HAVCR1 | c.-370A>T | 5'UTR (SNP) | VAF 50/90 reads (56%) | called by muse, varscan2
- HTR4 | c.1077-1022C>T | Intron (SNP) | VAF 32/183 reads (17%) | catalogued as COSV58807067; called by muse, mutect2, varscan2
- IFIH1 | c.-369G>C | 5'UTR (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- JUN | c.*111A>T | 3'UTR (SNP) | VAF 108/250 reads (43%) | called by muse, mutect2, varscan2
- KLK7 | c.-87G>T | 5'UTR (SNP) | VAF 68/114 reads (60%) | called by muse, mutect2, varscan2
- LINC00943 | n.1303T>C | RNA (SNP) | VAF 76/144 reads (53%) | called by muse, mutect2, varscan2
- LMO3 | c.*1031A>G | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- LPP | c.1240+3110T>C | Intron (SNP) | VAF 76/116 reads (66%) | called by muse, varscan2
- MICALL2 | c.1805+59A>T | Intron (SNP) | VAF 126/354 reads (36%) | called by muse, varscan2
- NKAIN1 | c.55-25T>C | Intron (SNP) | VAF 22/85 reads (26%) | catalogued as rs752622913; called by muse, mutect2, varscan2
- OBSCN | c.22385-129G>C | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ODC1 | c.*110C>T | 3'UTR (SNP) | VAF 222/365 reads (61%) | catalogued as rs1460456869, COSV99301318; called by muse, mutect2, varscan2
- OPN5 | c.-13G>C | 5'UTR (SNP) | VAF 98/239 reads (41%) | called by muse, mutect2, varscan2
- PDE8B | c.*398_*414del | 3'UTR (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- PTAR1 | c.*3088C>T | 3'UTR (SNP) | VAF 9/127 reads (7%) | catalogued as rs1181796424; called by muse, mutect2
- PTPRF | c.*881dup | 3'UTR (INS) | VAF 22/52 reads (42%) | catalogued as rs933691590; called by mutect2, varscan2
- QRSL1 | c.*747del | 3'UTR (DEL) | VAF 46/112 reads (41%) | called by mutect2, pindel, varscan2
- RAB3B | c.*1296G>A | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- RHOU | c.*1430dup | 3'UTR (INS) | VAF 27/225 reads (12%) | called by mutect2, pindel, varscan2
- RNU1-6P | chr1:16536133 G>A | 5'Flank (SNP) | VAF 31/274 reads (11%) | catalogued as rs1404576880; called by muse, mutect2, varscan2
- RSF1 | c.*5007T>A | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- SDC3 | c.*3240G>T | 3'UTR (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- SHISA3 | c.*716T>A | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*6209C>A | 3'UTR (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*1678T>A | 3'UTR (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- SLC35F5 | c.-50G>C | 5'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3627T>A | 5'UTR (SNP) | VAF 69/73 reads (95%) | called by muse, mutect2, varscan2
- SNORD116-27 | n.70A>G | RNA (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- SPAG9 | c.*533C>G | 3'UTR (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- SPECC1L | c.*2588C>G | 3'UTR (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- STK10 | c.*68A>T | 3'UTR (SNP) | VAF 64/117 reads (55%) | called by muse, mutect2, varscan2
- SYN3 | c.*1184T>C | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2
- TENM1 | c.*4199G>A | 3'UTR (SNP) | VAF 17/18 reads (94%) | catalogued as rs938258682; called by muse, mutect2, varscan2
- TMEM167A | c.*164G>C | 3'UTR (SNP) | VAF 32/160 reads (20%) | called by muse, varscan2
- TMEM222 | c.540-76G>A | Intron (SNP) | VAF 34/68 reads (50%) | called by mutect2, varscan2
- TSC22D2 | c.-939G>C | 5'UTR (SNP) | VAF 73/219 reads (33%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331471 G>A | 5'Flank (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- U2SURP | c.1854-54A>C | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- UBE2R2 | c.*191A>G | 3'UTR (SNP) | VAF 64/88 reads (73%) | called by muse, mutect2, varscan2
- ZNF107 | c.*1985T>A | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ZNF391 | c.*1729C>G | 3'UTR (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
